Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4FN, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4FN-01A (Primary Tumor).

[page 1 of 4]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Lymph-Node: RIGHT PARATRACHEAL LYMPH NODE AT THYMUS
2. Thyroid: Thyroid left paratracheal node - stitch left superior pole
3. Lymph node: Left level 2 lymph node
4. Lymph node: Left level 3 lymph node
5. Lymph node: Right level 2B lymph node
6. Lymph node: Right level 2,3,4 lymph nodes

Path: carcinoma, papillary and follicular 8340/3
Cyt: Carcinoma, papillary, thyroid 8260/3
Site: Thyroid, NOS c73.9
lw
10/2/12

Diagnosis

1. No pathological diagnosis: Lymph node, 1 (right paratracheal at thymus) excisional biopsy
2. Multifocal bilateral papillary carcinoma, dominant widely invasive mixed classical and follicular variant with focal tall cell change (<5%), 1.9 cm, isthmus; and follicular nodular disease with degeneration and oncocytic change: Thyroid
Metastatic papillary thyroid carcinoma: Lymph node, 3 of 3, isthmus
Metastatic papillary thyroid carcinoma: Lymph nodes, 4 of 8, central compartment
No pathological diagnosis: Parathyroid, right perithyroidal
Simple epithelial cysts: Parathyroid, central compartment
Ectopic serous and mucinous glands: Soft tissue, central compartment
- Total thyroidectomy specimen with central neck dissection
3. No pathological diagnosis: Lymph nodes, 5 (left neck level II) excisional biopsy
4. No pathological diagnosis: Lymph nodes, 6 (left neck level III) excisional biopsy
5. No pathological diagnosis: Lymph nodes, 2 (right neck level IIB) excisional biopsy
6. Micrometastatic papillary thyroid carcinoma: Lymph node, 1 of 9 (right neck level II, III and IV) excisional biopsy

Synoptic Data

Procedure:

Received:

Specimen Integrity:

Specimen Size:

Other: Total thyroidectomy with central and bilateral neck dissection specimen

Fresh

Intact

Right lobe:

3.8 cm

2.3 cm

[page 2 of 4]
Surgical Pathology Consultation Report

1.2 cm
Left lobe:
3.4 cm
2.3 cm
1.0 cm
Isthmus +/- pyramidal lobe:
3.2 cm
2.1 cm
1.4 cm
Central compartment:
4.3 cm
3.8 cm
1.1 cm
Right neck dissection:
6.8 cm
1.5 cm
1.5 cm
Left neck dissection:
2.8 cm
1.5 cm
1.4 cm
17.2 g
Specimen Weight:
Tumor Focality: Multifocal, bilateral
Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----
Tumor Laterality: Isthmus
Tumor Size: Greatest dimension: 1.9cm
Additional dimension: 1.7 cm
Additional dimension: 1.6 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, follicular variant
Papillary carcinoma, other variant: with focal tall cell change (<5%)
Classical (papillary) architecture
Follicular architecture
Classical cytomorphology
Tall cell cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.2mm
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
----- SECOND TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 0.5cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Classical (papillary) architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent minimal
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)

[page 3 of 4]
Surgical Pathology Consultation Report

Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid

Regional Lymph Nodes (pN): pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
Number of regional lymph nodes examined: 32
Number of regional lymph nodes involved: 8
Lymph Node, Extranodal Extension Not identified

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Parathyroid gland(s), within normal limits
Parathyroid gland(s), other: simple epithelial cysts
Other: additional multiple papillary microcarcinomas: 0.1 cm, right lobe and 0.05 cm, left lobe

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "right paratracheal lymph node at thymus" consists of a piece of fibroadipose tissue that measures 2.2 x 1.6 x 0.5 cm. It contains two query lymph nodes measuring 0.5 x 0.5 x 0.4 and 0.6 x 0.5 x 0.4 cm, respectively.

1A two lymph nodes

2. The specimen labeled with the patient's name and as "thyroid left paratracheal node stitch left superior pole" consists of an oriented thyroid gland with attached fibroadipose tissue on the inferior aspect that weighs 17.2 g. The right lobe measures 3.8 cm SI x 2.3 cm ML x 1.2 cm AP, the left lobe measures 3.4 cm SI x 2.3 cm ML x 1.0 cm AP and the isthmus measures 3.2 cm SI x 2.1 cm ML x 1.4 cm AP. The fibroadipose tissue measures 4.3 SI x 3.8 ML x 1.1 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands are identified grossly. The isthmus contains one well delineated nodule that measures 1.7 cm SI x 1.6 cm ML x 1.9 cm AP. A second well delineated nodule is identified in the inferior left lobe and measures 0.8 SI x 0.7 ML x 0.6 cm AP. Both nodules are tan and firm. Multiple lymph nodes are identified on the inferior soft tissue ranging in size from 0.2 x 0.2 x 0.2 cm to 1.7 x 0.9 x 0.8 cm. The remainder of the thyroid tissue is grossly unremarkable. Tissue is stored frozen. The remainder of the specimen is submitted as follows:

2A-E right lobe, superior to inferior

2F-H isthmus

2I-L left lobe, superior to inferior

2M one cystic lymph node bisected

2N multiple lymph nodes

3. The specimen labeled with the patient's name and as "left level II lymph node" consists of a piece of fibroadipose tissue that measures 2.8 x 1.5 x 1.4 cm. It contains multiple lymph nodes that range from 0.6 x 0.7 x 0.6 to 1.0 x 0.8 x 0.6 cm. Representative sections are submitted.

3A multiple lymph nodes

4. The specimen labeled with the patient's name and as "left level III lymph node" consists of two pieces of fibroadipose tissue that measures 1.3 x 1.5 x 0.8 and 2.4 x 1.5 x 1.3 cm. They contain multiple lymph nodes that range from 0.2 x 0.2 x 0.2 to 1.0 x 0.8 x 0.6 cm. Representative sections are submitted.

4A two lymph nodes

4B multiple lymph nodes

[page 4 of 4]
Surgical Pathology Consultation Report

5. The specimen labeled with the patient's name and as "right level IIB lymph nodes" consists of a piece of fibroadipose tissue that measures 1.3 x 0.8 x 0.5 cm. It contains two lymph nodes that measures 0.3 x 0.4 x 0.4 and 0.4 x 0.4 x 0.4 cm. Representative sections are submitted.

5A two lymph nodes

6. The specimen labeled with the patient's name and as "right level II, III and IV" consists of a piece of unoriented fibroadipose tissue that measures 6.8 x 1.5 x 1.5 cm. It contains multiple lymph nodes that range from 0.2 x 0.3 x 0.2 to 1.2 x 0.9 x 0.9 cm. The lymph nodes are sequentially submitted after the specimen is trisected with the lymph nodes submitted in as follows:

6A one lymph node bisected

6B multiple lymph nodes

6C one lymph node bisected

6D one lymph node bisected

6E multiple lymph nodes

Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file d8f005d4-c3c0-4bdb-bdb0-acbc16618329 (TCGA-EM-A4FN.45A213AB-38E7-4D7F-8E38-5CC140570891.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).